Surgical pathology report (de-identified scan), TCGA case TCGA-06-2562, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-2562-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Report

TCGA-06-2562

CLINICAL HISTORY

[REDACTED] with right-sided tingling and numbness experienced right sided seizure, and had at surgery a high histological grade glioma. Currently, residual tumor has increased in size, with significant mass effect.

OPERATIVE DIAGNOSES

Left parietal occipital tumor

Operation/Specimen: A: Left parietal tumor, biopsy
B: Brain tumor, left, excision biopsy

PATHOLOGICAL DIAGNOSIS:

A, B. Brain, left parietal, excisional biopsy and excision:

1. Glioblastoma.
2. MIB-1 proliferation index: 33%.
- See Microscopy Description and Comment.

COMMENT

The specimens consist of fragments of cerebrum that are infiltrated and extensively effaced by an astrocytic neoplastic proliferation with nuclear anaplasia, mitotic activity, a high proliferation index, prominent microvascular cellular proliferation, and zones of tumor necrosis.

The findings are those of a glioblastoma (WHO grade IV/IV).

PROCEDURES/ADDENDA

MGMT Promoter Methylation

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

POSITIVE: Methylated MGMT promoter is detected.

[page 2 of 4]
Results-Comments

Testing performed on tumor paraffin block

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of DNA followed by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

Interpretation

NEGATIVE - No evidence of EGFRvIII mutation is detected

Results-Comments

TEST DESCRIPTION: Testing performed on RNA extracted from tumor paraffin block

RNA quality: Good

The epidermal growth factor receptor (EGFR) is an attractive molecular target in glioblastoma because it is amplified, overexpressed, and/or mutated in up to 40% to 50% of patients. Epidermal growth factor receptor variant III (EGFRvIII) is an oncogenic, constitutively active mutant form of EGFR that is commonly expressed in glioblastoma. Cell culture and in vivo models of glioblastoma have demonstrated EGFRvIII as defining prognostically distinct subgroups of glioblastomas. Additionally, the presence of EGFRvIII has been shown to sensitize tumors to EGFR tyrosine kinase inhibitors when the tumor suppressor protein PTEN is intact. RNA is extracted from formalin fixed, paraffin embedded tissue samples and reverse transcribed to cDNA. The cDNA is then amplified using standard PCR technique for DNA templates. PCR products are detected by gel electrophoresis. The limit of detection of this assay has been determined to be approximately 5 mutant cells in 100 normal cells.

FDA Comment: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

[page 3 of 4]
=====

INTRA-OPERATIVE CONSULTATION

A.

Left parietal tumor, biopsy, touch prep and smears: High histological grade glioma (C/W glioblastoma). [REDACTED] Touch preparation smears performed at [REDACTED] and results reported to the Physician of Record. [REDACTED]

[REDACTED]

GROSS DESCRIPTION

A.

"Brain tumor," received fresh, three fragments, 0.8 cm in aggregate. Soft, glistening, reddish-tan. In total, A2.

B.

SPECIMEN: Brain tumor, left

FIXATIVE: Formalin

GENERAL: Received is a 2.2 x 1.5 x 0.5 cm aggregate of irregular tan brown hemorrhagic soft rubbery tissue fragments.

SECTIONS: B1-submitted entirely

[REDACTED]

MICROSCOPIC DESCRIPTION

IMMUNOHISTOCHEMISTRY: The GFAP depicts the strong gliofibrillogenesis of the tumor. A great majority of neoplastic cells strongly over express the p53 protein. With the MIB-1 there is a proliferation index of about 33% in the more active areas. The neoplasm has immunoreactivity with EMA.

ICD-9(s):

239.6 239.6

[REDACTED]

Histo Data

Part A: Left parietal tumor, biopsy

Taken:	Received:		
Stain/cnt	Block	Ordered	Comment
EGFR VIII-curls x 1	1	[REDACTED]	No microdissection needed!
EMA-DA x 1	1	[REDACTED]	
mGFAP-DA x 1	1	[REDACTED]	
H/E x 1	1	[REDACTED]	
MGMT-curls x 1	1	[REDACTED]	
MIB1-DA x 1	1	[REDACTED]	
p53DO7 x 1	1	[REDACTED]	
3 H/E x 1	1	[REDACTED]	

Part B: Brain tumor, left, excision biopsy

Taken: [REDACTED] Received: [REDACTED]

[page 4 of 4]
[REDACTED]

Stain/cnt	Block	Ordered	Comment
4/E x 1	1	[REDACTED]	

*** End of Report ***

Source: NCI Genomic Data Commons file 30388166-2594-4db9-9f66-63e0f35ae069 (TCGA-06-2562.9E6CD324-7E45-4736-86AD-92B44321B0D7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).